Surgical pathology report (de-identified scan), TCGA case TCGA-14-1795, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1795-01A (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

TCGA-14-1795

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: AP REPORT
Encounter info:

* Final Report *

AP REPORT

Patient: Accession Number:
Patient Number:
Financial Number:
Room/Bed: PT:
Admitting Physician:
Ordering Physician:

Date Collected:
Date Received:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, LEFT FRONTAL, BIOPSY, FS1A, TP1A:
- GLIOBLASTOMA MULTIFORME.
2. BRAIN, LEFT FRONTAL, EXCISION:
- GLIOBLASTOMA MULTIFORME.

(Electronic Signature)

SPECIMEN:

1. Left frontal brain lesion.
2. Left frontal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Left frontal brain lesion. Left frontal craniotomy for tumor resection.

GROSS DESCRIPTION:

Two specimens are received, the first fresh for intraoperative consultation, and the second in formalin, each labeled with the patient's name and hospital

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
AP Report

* Final Report *

TCGA-14-1795

number.

Specimen #1 is labeled as "left frontal brain lesion." The specimen consists of three pieces of soft pink tissue measuring in aggregate 1.0 x 0.8 x 0.4 cm. A portion is submitted for touch prep evaluation. A representative section is submitted for intraoperative consultation and frozen section diagnosis, and the remainder of the cryoblock is submitted in cassette "FS1A." The remainder of the tissue is entirely submitted in cassette "1B."

Specimen #2 is labeled as "left frontal brain lesion." The specimen consists of multiple pieces of hemorrhagic brain tissue, the largest measuring 3.0 x 2.0 x 1.5 cm, and the remaining pieces measuring 2.2 x 0.7 x 0.5 cm in aggregate. Serial sectioning of the largest piece shows an irregular, poorly circumscribed, yellow soft mass extending to the margins of resection. The largest piece is inked blue prior to sectioning. The specimen is entirely submitted in cassettes "2A" through "2F."

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: BRAIN, LEFT FRONTAL, BIOPSY (FROZEN SECTION, TOUCH PREPARATION):
GLIOBLASTOMA MULTIFORME.

Pathologist:

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Medical Records

Page 1 (End of Report)

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 902187e3-a5cc-4c7e-93ca-4be8f3d986b7 (TCGA-14-1795.1619DEF7-F24E-49CF-B2FB-1879951E0C62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).